MMRF case MMRF_2446 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6dafa05a-8097-44a9-96eb-2b8131fb5731

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 50 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 50.5 years (18,430 days); ISS stage: II; Days to last known disease status: 729 days (2.0 years); Days to last follow up: 729 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 93 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 120 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 260 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1 (ECOG 2): M Protein 1.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.6 mg/dL; Immunoglobulin G 16 g/L; Immunoglobulin A 0.439 g/L; Immunoglobulin M 0.536 g/L; Beta 2 Microglobulin 4.6 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 325 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 45 g/L; Total Protein 8.6 g/dL; Glucose 5.45 mmol/L.
- Day 97 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 5.02 g/L; Immunoglobulin A 0.442 g/L; Immunoglobulin M 0.426 g/L; Lactate Dehydrogenase 4 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 39.7 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.83 mmol/L.
- Day 154 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 7.86 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.539 g/L; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 7.4 g/dL; Glucose 6.33 mmol/L.
- Day 232 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 9.5 g/L; Immunoglobulin A 0.615 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 6.44 mmol/L.
- Day 316: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 9.58 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.4 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 4.73 mmol/L.
- Day 456 (ECOG 0): Hemoglobin 7.94 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 299 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 8 g/dL; Glucose 5.61 mmol/L.
- Day 547 (ECOG 1): Hemoglobin 7.87 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.08 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 7.26 mmol/L.
- Day 631 (ECOG 1): Lactate Dehydrogenase 2.15 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 257 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 5.94 mmol/L.
- Day 729 (ECOG 1): Hemoglobin 7.81 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 287 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 5.34 mmol/L.

Other clinical attributes
- Day -1: Weight: 82 kg; Height: 152 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2446_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_2446_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
